Surgical pathology report (de-identified scan), TCGA case TCGA-05-4382, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4382-01A (Primary Tumor).

Main diagnosis/diagnoses:

Primarily evidently a peripheral bronchopulmonary, histologically mixed large-cell and clear-cell adenocarcinoma of the left upper lobe with very predominant solid and small acinar component and localization in S3.

TNM classification on the basis of this material pT2 pN0 pMX R0, stage IB.
C34.1; M 8255/3.

Comment/supplementary remark:

The carcinoma has focally infiltrated the visceral pleura. The resection margin of bronchus and vessels and all lymph nodes identified and removed are tumor-free.

Source: NCI Genomic Data Commons file e3d3a834-0e43-4ebd-a505-678c29bce6b9 (TCGA-05-4382.952C0F32-1472-49E1-8334-B0F1DE4AC921.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).